Somatic mutation profile of tumor specimen C3N-01083-02 (aliquot CPT0211850006) from CPTAC case C3N-01083, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01083-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e435405-9890-4614-b130-0227401030c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01083-71 (Blood Derived Normal), aliquot CPT0211960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2794cc5-01ac-4210-8476-bfbbc4cdacc7

The open-access MAF lists 92 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Intron 4, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, Splice Site 2, 5'UTR 2, 3'UTR 2, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+2T>C p.X155_splice | Splice Site (SNP) | VAF 43/314 reads (14%) | hotspot (GDC flag); catalogued as rs5030814, CS961707, COSV56543181, COSV56545468, COSV56553134; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ACTR8 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51638056; called by muse, mutect2, varscan2
- ALDH4A1 | c.959T>G p.F320C | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs552112789; called by muse, mutect2
- CIBAR1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63897425; called by muse, mutect2, varscan2
- FLG | c.6878G>T p.G2293V | Missense Mutation (SNP) | VAF 75/597 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV64246584; called by muse, mutect2, varscan2
- GNAS | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 108/877 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs1334915421, COSV58340510; called by muse, mutect2, varscan2
- GYG2 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.842); catalogued as COSV100088631; called by muse, mutect2
- HPGD | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 45/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171070026; called by muse, mutect2, varscan2
- KCNC3 | c.2136C>G p.D712E | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1421966038; called by muse, mutect2, varscan2
- KIF18B | c.1378C>T p.P460S (on ENST00000593135 / NM_001265577.2; = p.P472S on NM_001264573.2) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59271486; called by muse, mutect2, varscan2
- KIT | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs779103998, COSV55419763, COSV55426274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAST3 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1246051403; called by muse, mutect2, varscan2
- METTL1 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs150140634; called by muse, mutect2, varscan2
- NUP210 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477802749; called by muse, mutect2
- PLIN4 | c.2836G>A p.A946T (on ENST00000301286; = p.A961T on NM_001367868.2) | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201223343, COSV56691084; called by muse, mutect2, varscan2
- REST | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1401967892; called by muse, mutect2, varscan2
- REXO1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1380984237; called by muse, mutect2
- SPICE1 | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 21/159 reads (13%) | catalogued as rs1407020061; called by muse, mutect2, varscan2
- TBX3 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 88/700 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57471295; called by muse, mutect2, varscan2
- TNFRSF8 | c.1335+1G>A p.X445_splice | Splice Site (SNP) | VAF 27/188 reads (14%) | catalogued as COSV55795731; called by muse, mutect2, varscan2
- UTP4 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 63/481 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs751461578, COSV100076935; called by muse, mutect2, varscan2
- VPS13B | c.7297A>G p.S2433G | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs1563907974; called by muse, mutect2, varscan2
- ZNF529 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs568515212, COSV61899845, COSV61901686; called by muse, mutect2, varscan2
- AC013489.1 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ADSL | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 37/358 reads (10%) | called by muse, mutect2, varscan2
- CCDC180 | c.1606del p.T536Hfs*13 | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- CXorf21 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGAT2 | c.180dup p.R61* | Frame Shift Ins (INS) | VAF 20/210 reads (10%) | called by mutect2, pindel, varscan2
- DOCK7 | c.4009A>C p.K1337Q (on ENST00000635253 / NM_001367561.1; = p.K1306Q on NM_033407.3) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFS | c.1173A>C p.K391N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- FBN3 | c.4784A>G p.H1595R | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FBXW10 | c.2207T>A p.V736E | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FRA10AC1 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IAPP | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR2 | c.7198G>A p.V2400I | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ITPRID1 | c.2705A>C p.E902A | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KMT5A | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAST2 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- MFHAS1 | c.2195G>T p.R732L | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MSH2 | c.2126del p.L709* | Frame Shift Del (DEL) | VAF 59/464 reads (13%) | called by mutect2, pindel, varscan2
- MUC16 | c.39571A>T p.K13191* | Nonsense Mutation (SNP) | VAF 33/190 reads (17%) | called by muse, mutect2, varscan2
- NAAA | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAT8 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- NELL2 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCNX3 | c.2162T>C p.L721P | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POLR2A | c.4124G>A p.R1375Q | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF17 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PTK7 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PTPN11 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 79/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- REPIN1 | c.270T>A p.C90* | Nonsense Mutation (SNP) | VAF 91/590 reads (15%) | called by muse, mutect2, varscan2
- SEPSECS | c.1188del p.F396Lfs*19 | Frame Shift Del (DEL) | VAF 50/395 reads (13%) | called by mutect2, pindel, varscan2
- SHANK1 | c.2559dup p.G854Rfs*6 | Frame Shift Ins (INS) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- SHANK2 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPINK9 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- TMEM267 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- UGT1A7 | c.410T>C p.L137S | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UNC5D | c.2114_2137del p.D705_C712del | In Frame Del (DEL) | VAF 72/497 reads (14%) | called by mutect2, pindel
- USP28 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ZNF185 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ADSL | c.1065G>C p.L355= | Silent (SNP) | VAF 37/359 reads (10%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3981G>A p.T1327= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs901606215, COSV51850980; called by muse, mutect2, varscan2
- ARHGEF15 | c.573G>T p.G191= | Silent (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- C3 | c.3021C>A p.P1007= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- CA5B | c.513A>C p.A171= | Silent (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- DGKA | c.1866C>A p.I622= | Silent (SNP) | VAF 39/311 reads (13%) | catalogued as COSV59385339; called by muse, mutect2, varscan2
- EPHA5 | c.222A>G p.G74= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs765069038; called by muse, mutect2
- EPHB4 | c.2295G>A p.L765= | Silent (SNP) | VAF 44/362 reads (12%) | called by muse, mutect2, varscan2
- FGF13 | c.141C>T p.S47= | Silent (SNP) | VAF 26/200 reads (13%) | called by muse, mutect2, varscan2
- HFE | c.660G>T p.V220= | Silent (SNP) | VAF 66/494 reads (13%) | called by muse, mutect2, varscan2
- IGFBP3 | c.774G>A p.K258= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs147067231; called by muse, mutect2, varscan2
- NOXO1 | c.654C>G p.P218= (on ENST00000397280 / NM_172168.3; = p.P212= on NM_144603.4) | Silent (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2, varscan2
- NPAS3 | c.117C>A p.I39= | Silent (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- OR2G6 | c.726G>C p.S242= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs552819557, COSV58573606, COSV58575678; called by muse, mutect2, varscan2
- SALL3 | c.2700G>A p.S900= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs759723331, COSV73306177; called by muse, mutect2, varscan2
- TMEM145 | c.1098C>T p.A366= | Silent (SNP) | VAF 12/302 reads (4%) | catalogued as rs1296934723; called by muse, mutect2
- TSR1 | c.756C>T p.Y252= | Silent (SNP) | VAF 59/328 reads (18%) | called by muse, mutect2, varscan2
- UBR2 | c.600G>A p.R200= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- ZBTB3 | c.1347C>G p.P449= | Silent (SNP) | VAF 31/221 reads (14%) | catalogued as rs1565178392; called by muse, mutect2, varscan2
- ZFPM1 | c.2373C>T p.A791= | Silent (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.813C>A p.T271= | Silent (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- B3GAT3 | c.83-565G>C | Intron (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- BOD1P2 | n.87G>A | RNA (SNP) | VAF 5/35 reads (14%) | catalogued as rs1477034454; called by muse, mutect2, varscan2
- EFHC1 | c.*1925C>G | 3'UTR (SNP) | VAF 56/436 reads (13%) | called by muse, mutect2, varscan2
- EIF2B4 | c.591-34C>T | Intron (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- FAM205BP | n.1457C>G | RNA (SNP) | VAF 14/94 reads (15%) | catalogued as rs1451739766; called by muse, mutect2, varscan2
- GAS8 | c.*613T>C | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- GVINP1 | n.5051del | RNA (DEL) | VAF 36/259 reads (14%) | called by mutect2, pindel*, varscan2*
- KDM4C | c.-1C>T | 5'UTR (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- PTPA | chr9:129110985 G>T | 5'Flank (SNP) | VAF 34/276 reads (12%) | called by muse, mutect2, varscan2
- REL | c.-68G>A | 5'UTR (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- TPP1 | c.1075+50G>C | Intron (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- ZNF419 | c.72+23C>T | Intron (SNP) | VAF 15/194 reads (8%) | catalogued as rs1258194319; called by muse, mutect2
